Somatic mutation profile of tumor specimen 0DX4FT from CCDI case PBCPXT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.8 years (1,764 days).
Specimen 0DX4FT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75995162-1e2e-4531-a1fb-9463bff03cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4EU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe13deed-45c3-43ec-9a76-c7f1433ac3c2

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 235/760 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, varscan2
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 120/412 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, varscan2
- OR4K5 | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 158/840 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV60002404, COSV60004958; called by muse, varscan2
- ZNF33A | c.1184A>G p.H395R (on ENST00000458705 / NM_006974.3; = p.H396R on NM_006954.2) | Missense Mutation (SNP) | VAF 157/591 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.832); catalogued as rs1450422916, COSV100275594; called by muse, varscan2
- CRHBP | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 140/514 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDAN1 | c.1197G>A p.L399= | Silent (SNP) | VAF 96/306 reads (31%) | catalogued as rs1325431232; called by muse, varscan2
- OR1D2 | c.645C>T p.I215= | Silent (SNP) | VAF 116/402 reads (29%) | catalogued as rs139929114; called by muse, varscan2
- SRCIN1 | c.1060C>T p.L354= (on ENST00000621492; = p.L320= on NM_025248.3) | Silent (SNP) | VAF 65/188 reads (35%) | called by muse, varscan2
- TACSTD2 | c.372G>T p.V124= | Silent (SNP) | VAF 36/129 reads (28%) | called by muse, varscan2
- UBQLN2 | c.159G>A p.S53= | Silent (SNP) | VAF 80/508 reads (16%) | called by muse, varscan2
- TBCK | c.*43A>C | 3'UTR (SNP) | VAF 62/236 reads (26%) | called by muse, varscan2
